Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A4Z0, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A4Z0-01A (Primary Tumor).

Patient: XXX

PESEL: XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Stomach cancer**

Date of admission: (urgency: Standard)

Material:

1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on:

Stomach adenocarcinoma mucinous with metastases to lymph nodes (G3, pT2, pN1).

(8140/3 T-63000)*

Macroscopic description:

The specimen containing the stomach, incised along the lesser curvature sized 19 x 13 cm. Tumour with ulceration sized 7 x 5 x 2 cm in the pyloric region. Distance from the proximal end: 12 cm, from distal end: 0.5 cm.

Microscopic description:

Gastric adenocarcinoma mucocellulare (G3, diffuse type acc. to Lauren class.). The lesion invades the submucosa and the muscular layer of the stomach wall. Incision lines free of neoplastic lesions.

Metastases to 3/10 lymph nodes.

Assistant:

Edited by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-0-3

adenocarcinoma, mucinosa, NOS 8480/3

c p c f Site: Stomach, antrum C16.3

Path Stomach, NOS C16.9

hu
11/4/12

Primary Tumour Site Discrepancy		
Pr. or Malignancy History		

Source: NCI Genomic Data Commons file a67b1b0a-51a6-4b4a-a68e-14ce67abeb86 (TCGA-D7-A4Z0.372DC7F5-D739-42B5-8899-CD22F6B219D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).